Somatic mutation profile of tumor specimen C3N-00150-01 (aliquot CPT0066480009) from CPTAC case C3N-00150, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.5 years (20,286 days).
Specimen C3N-00150-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fff601b9-6669-4a42-b1c6-f005559145f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00150-31 (Blood Derived Normal), aliquot CPT0071650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76f348d0-6754-4753-9786-55166ca1237f

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 7, Frame Shift Del 5, Splice Site 4, Intron 3, 3'UTR 2, Frame Shift Ins 2, In Frame Del 1, 5'UTR 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP2 | c.2683C>G p.L895V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.699); catalogued as rs373281502; called by muse, mutect2, varscan2
- CEMIP | c.965-1G>C p.X322_splice | Splice Site (SNP) | VAF 36/428 reads (8%) | catalogued as rs769389649; called by muse, mutect2
- CTNNA1 | c.1057G>C p.G353R | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.315); catalogued as rs758284033; ClinVar: uncertain significance; called by muse, mutect2
- DHCR7 | c.760T>C p.S254P | Missense Mutation (SNP) | VAF 42/462 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM034225; called by muse, mutect2
- DMXL2 | c.3242G>A p.R1081H | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757597201; called by muse, mutect2
- DNAJB5 | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as rs1272825498; called by muse, mutect2, varscan2
- RASGRP4 | c.1477C>G p.R493G | Missense Mutation (SNP) | VAF 26/363 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV53039900, COSV99384963; called by muse, mutect2
- RBBP5 | c.222G>T p.W74C | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1182081700, COSV52705946; called by muse, varscan2
- RFX3 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 28/576 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as rs1213429746, COSV56507633; called by muse, mutect2
- SOD1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV54256823; called by muse, mutect2
- TBX3 | c.1999G>A p.A667T (on ENST00000257566 / NM_016569.4; = p.A647T on NM_005996.4) | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1268167495; called by muse, mutect2
- TRIM38 | c.392A>T p.D131V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs1182611170; called by muse, varscan2
- ZDHHC11B | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1175348274; called by muse, mutect2, varscan2
- ZNF638 | c.3103G>T p.D1035Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV52485566; called by muse, mutect2
- AACS | c.1881+1G>T p.X627_splice | Splice Site (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- AKAP4 | c.1509G>T p.E503D | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ALOX12B | c.1224del p.F409Sfs*6 | Frame Shift Del (DEL) | VAF 37/351 reads (11%) | called by mutect2, pindel, varscan2
- ASPSCR1 | c.1348T>G p.F450V | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CDKN2D | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2
- CERKL | c.1208A>C p.E403A (on ENST00000339098 / NM_001030311.2; = p.E377A on NM_201548.5) | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CPLANE1 | c.8423_8424del p.S2808Cfs*9 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel, varscan2
- CUL3 | c.1179_1188delinsAAAAAAAAAA p.D393_L396delinsEKKK | Missense Mutation (ONP) | VAF 6/64 reads (9%) | called by mutect2*, pindel
- CUL9 | c.1682A>C p.N561T | Missense Mutation (SNP) | VAF 48/449 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CUL9 | c.4687G>T p.G1563C | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX59 | c.670_675del p.E224_V225del | In Frame Del (DEL) | VAF 12/140 reads (9%) | called by mutect2, pindel
- DROSHA | c.2995T>C p.Y999H | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- E2F2 | c.927G>C p.E309D | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ELF3 | c.177G>C p.W59C | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ESF1 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- FBLN1 | c.1385A>G p.Q462R | Missense Mutation (SNP) | VAF 63/626 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FYCO1 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- GCGR | c.949-2A>G p.X317_splice | Splice Site (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- GRAMD1B | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GRB2 | c.556A>G p.M186V | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- KMT2A | c.9122_9125del p.I3041Rfs*30 | Frame Shift Del (DEL) | VAF 34/213 reads (16%) | called by mutect2, pindel, varscan2
- L3MBTL2 | c.1051_1052dup p.R352Vfs*24 | Frame Shift Ins (INS) | VAF 34/334 reads (10%) | called by mutect2, pindel
- MAPK9 | c.512G>C p.G171A | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NLRX1 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NPHP3 | c.3847T>A p.L1283I | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRSS36 | c.1601G>T p.C534F | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIRT1 | c.1840del p.T614Lfs*7 | Frame Shift Del (DEL) | VAF 10/89 reads (11%) | called by mutect2, pindel, varscan2
- SLC25A39 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2
- SNAPC4 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.069); called by muse, mutect2
- SNCG | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2
- TIAL1 | c.372-2A>G p.X124_splice | Splice Site (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- TMEM26 | c.471A>G p.I157M | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- TRNT1 | c.614del p.Y205Lfs*5 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- UGT1A4 | c.354_355insGG p.N119Gfs*20 | Frame Shift Ins (INS) | VAF 40/394 reads (10%) | called by mutect2, pindel
- AMPD3 | c.306C>T p.A102= (on ENST00000396553 / NM_001025389.2; = p.A111= on NM_000480.3) | Silent (SNP) | VAF 60/608 reads (10%) | called by muse, mutect2
- CACNA1H | c.2658C>T p.F886= | Silent (SNP) | VAF 23/279 reads (8%) | catalogued as rs1202009471; called by muse, mutect2
- CHD8 | c.3091A>C p.R1031= (on ENST00000646647 / NM_001170629.2; = p.R752= on NM_020920.4) | Silent (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2
- GRIN3A | c.744T>C p.S248= | Silent (SNP) | VAF 27/247 reads (11%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1209C>A p.T403= (on ENST00000485419 / NM_001197113.1; = p.T327= on NM_014575.3) | Silent (SNP) | VAF 23/214 reads (11%) | called by muse, mutect2, varscan2
- NUP160 | c.1866A>T p.S622= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- SLC1A6 | c.1476C>T p.L492= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as COSV99693773; called by muse, mutect2, varscan2
- ANKRD26 | c.1635+2119C>T | Intron (SNP) | VAF 11/118 reads (9%) | catalogued as rs1213133783; called by muse, mutect2
- BTN3A2 | c.937+14C>T | Intron (SNP) | VAF 11/124 reads (9%) | catalogued as rs1439806381; called by muse, mutect2
- INKA1 | c.-21G>A | 5'UTR (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- RN7SL484P | chr15:99792891 G>C | 3'Flank (SNP) | VAF 33/306 reads (11%) | called by muse, mutect2, varscan2
- RPL13AP20 | n.399A>C | RNA (SNP) | VAF 56/605 reads (9%) | called by muse, mutect2
- SLC7A13 | c.1180-1001G>T | Intron (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- TMEM169 | c.*11A>T | 3'UTR (SNP) | VAF 38/318 reads (12%) | called by muse, mutect2, varscan2
- XIAP | c.*4819T>C | 3'UTR (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
